Somatic mutation profile of tumor specimen TCGA-KN-8432-01A (aliquot TCGA-KN-8432-01A-11D-2310-10) from TCGA case TCGA-KN-8432, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 86.5 years (31,591 days).
Specimen TCGA-KN-8432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51054766-db83-4068-9573-a86e95b75db6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8432-11A (Solid Tissue Normal), aliquot TCGA-KN-8432-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a946d1d6-7dbd-4829-a123-c9cabbe2cdd7

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, In Frame Del 3, Frame Shift Del 2, Splice Site 2, Splice Region 2, Nonsense Mutation 2, 3'UTR 2, Translation Start Site 1, 5'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FERMT3 | c.1537C>T p.R513* (on ENST00000279227 / NM_178443.3; = p.R509* on NM_031471.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as rs121918295, CM091836; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs887675747, COSV60093530; called by muse, mutect2, varscan2
- ARHGEF2 | c.992C>T p.A331V (on ENST00000361247 / NM_001162383.2; = p.A303V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs763347486; called by muse, mutect2, varscan2
- CAPNS1 | c.207C>T p.I69= | Splice Region (SNP) | VAF 36/91 reads (40%) | catalogued as rs1450684471, COSV99874714; called by muse, mutect2, varscan2
- EIF2S3 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99451166; called by muse, mutect2
- ESR2 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747036560; called by muse, mutect2, varscan2
- FRYL | c.8146-1G>C p.X2716_splice | Splice Site (SNP) | VAF 14/270 reads (5%) | catalogued as COSV99978258; called by muse, mutect2
- KCNN4 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); catalogued as rs1274582578; called by muse, mutect2, varscan2
- KCNQ5 | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100573227; called by muse, mutect2
- KIR2DL1 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99383677; called by muse, mutect2, varscan2
- KRTAP10-4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs782393210; called by muse, mutect2, varscan2
- LAMA4 | c.1669-1G>C p.X557_splice (on ENST00000230538 / NM_001105206.3; = p.X550_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100039516; called by muse, mutect2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2
- SDHA | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99372230; called by muse, mutect2
- SLA2 | c.381A>T p.R127S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as rs889728725; called by muse, mutect2
- SUPT6H | c.4900C>T p.Q1634* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99973112; called by muse, mutect2
- TMEM51 | c.421A>T p.N141Y | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV101051578; called by muse, mutect2
- TRPM7 | c.4321G>A p.V1441I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.058); catalogued as COSV100540347; called by muse, mutect2
- UBQLN3 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1369538895, COSV100293973; called by muse, mutect2
- VIRMA | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99889527; called by muse, mutect2
- VRTN | c.1230G>C p.E410D | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV99832492; called by muse, mutect2
- ZNF592 | c.2378A>G p.Y793C | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370083133; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.352A>C p.T118P | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT tolerated, low confidence (0.05); called by muse, mutect2, varscan2
- AHR | c.453T>A p.S151= | Splice Region (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7844A>G p.D2615G | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATG2A | c.2114A>G p.Y705C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CD276 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CWF19L2 | c.274_282del p.E92_K94del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- FLAD1 | c.1675C>G p.L559V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNRNPLL | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 74/95 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTCH1 | c.981del p.F328Sfs*3 (on ENST00000373627 / NM_001271641.1; = p.F311Sfs*3 on NM_014341.2) | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- MTTP | c.90_92del p.D31del | In Frame Del (DEL) | VAF 18/166 reads (11%) | called by mutect2, pindel, varscan2
- NLRC5 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- NPY1R | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.438); called by muse, mutect2
- OR52N1 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PATJ | c.3526A>G p.I1176V | Missense Mutation (SNP) | VAF 105/141 reads (74%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PCDHGB5 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD23B | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SLC25A36 | c.841_851del p.Y281Dfs*19 (on ENST00000324194 / NM_001104647.3; = p.Y280Dfs*19 on NM_018155.3) | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- SQOR | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- SRSF7 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SULF2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TLE1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- TYRP1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2
- WNT1 | c.212_220del p.L71_R73del | In Frame Del (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- ZNF142 | c.1779G>C p.K593N (on ENST00000411696 / NM_001379660.1; = p.K393N on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ALPG | c.1236C>T p.Y412= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as rs563231782, COSV99779216; called by muse, mutect2, varscan2
- FANCA | c.2136G>A p.E712= | Silent (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- IKZF1 | c.300C>T p.G100= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- MAGED2 | c.864G>A p.K288= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs1162597231; called by muse, mutect2, varscan2
- RGL1 | c.1893G>A p.T631= (on ENST00000360851 / NM_001297672.2; = p.T666= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SCN4A | c.3963C>T p.N1321= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs747602881, COSV71129384; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUSD4 | c.153C>T p.F51= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1468922571, COSV100663607; called by muse, mutect2
- ZNF264 | c.1614C>T p.P538= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as rs1206005682, COSV54043479, COSV99567441; called by muse, mutect2
- ARMCX5-GPRASP2 | c.*1666A>T | 3'UTR (SNP) | VAF 13/170 reads (8%) | catalogued as COSV100771996; called by muse, mutect2
- C2CD4A | c.*260C>A | 3'UTR (SNP) | VAF 36/191 reads (19%) | catalogued as COSV100831142; called by muse, mutect2, varscan2
- DUS2 | c.-19+628_-19+630dup | Intron (INS) | VAF 20/50 reads (40%) | called by pindel, varscan2
- N4BP2L2 | chr13:32442745 A>C | 3'Flank (SNP) | VAF 20/33 reads (61%) | called by muse, mutect2, varscan2
- TLE1 | c.-1G>A | 5'UTR (SNP) | VAF 17/39 reads (44%) | catalogued as rs922340088, COSV100916028; called by muse, mutect2, varscan2
